Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5496, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5496-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 6.5. The patient also has a history of biopsy on [REDACTED]. This biopsy reveals: moderately-differentiated prostatic adenocarcinoma, Gleason score 3+3 = 6 in the right base, right mid, right apex, left base, left mid and left apex of the prostate. The patient also has a history of laparoscopic cholecystectomy and gallstone pancreatitis four years ago.
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical prostatectomy.

FINAL DIAGNOSIS:

TCGA - EJ - 5496

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN TEN (10) LYMPH NODES EXAMINED.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN SIXTEEN (16) LYMPH NODES EXAMINED.

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
- B. TUMOR INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.8 CM.
- C. THE TUMOR INVOLVES 25% OF THE TOTAL PROSTATE VOLUME.
- D. THE TUMOR IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF TUMOR.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- G. FOCAL PERINEURAL INVASION IS IDENTIFIED.
- H. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. TNM PATHOLOGIC STAGE = pT2c N0 MX.
- K. TNM HISTOLOGIC GRADE = G3.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 6.5
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	30%
WEIGHT OF PROSTATE:	79.68gm
TUMOR SIZE:	Maximum dimension: 1.8 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	26
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file a51e0dc0-f97a-40ca-b225-ab78b6ca97a1 (TCGA-EJ-5496.80E82784-0BCA-4657-9C9F-E9B860DC09BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).